Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A16I, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A16I-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Carcinoma, Serous, NOS

8441/3 12/9/10

Surgical Pathology

Site Code: Endometrium C54.1

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 B1 B2 B3 B4 C1 C2 C3 C4 C5 C6
C7 C8 D1
D2 D3 D4 D5 D6 D7 D8 E1 E2 E3 E4 E5 E6 E7 E8 E9 E10 E11
E12 F1 F2 F3

Uterus, right ovary (2.2 x 1.2 x 1.0 cm) with 9.2 cm
segment of
right fallopian tube, and left ovary (2.7 x 1.4 x 1.2 cm)
with 9.8
cm segment of left fallopian tube together weighing 150.0
grams,
portion of omentum (24.0 x 4.2 x 1.9 cm), separately
submitted
bilateral para-aortic above the inferior mesenteric
artery,
bilateral para-aortic lymph nodes below the inferior
mesenteric
artery, laparoscopic right pelvic lymph nodes, and
laparoscopic left
pelvic lymph nodes,

DIAGNOSIS:

Uterus, bilateral ovaries, and fallopian tubes; abdominal
hysterectomy and bilateral salpingo-oophorectomy:
Invasive high
grade papillary serous carcinoma forming a main exophytic
mass (2.9
x 2.1 x 1.1 cm) involving the left lateral wall of lower
uterine
segment. A separate non-invasive, high grade papillary
serous
carcinoma forming a mass (1.3 x 1.0 x 0.8 cm) arising
within in an
endometrial polyp is also identified. The invasive tumor
extends 0.8
cm into the myometrium (1.2 cm total myometrial thickness)
within
the lower uterine segment. Multiple (2) benign leiomyomata
(4
intramural, 1.2 to 3.4 cm) are identified. The left tube
and

[page 2 of 2]
bilateral ovaries are uninvolved. The right tube shows a paratubal cyst. Multiple (2) calcified nodules are identified within the left and right adnexa.

Omentum, omentectomy: Mature adipose tissue, negative for tumor.

Lymph nodes, bilateral para-aortic above and below the inferior mesenteric artery, excisions: Multiple bilateral para-aortic lymph nodes (11 above and 11 below the inferior mesenteric artery) are negative for tumor.

Lymph nodes, laparoscopic right pelvic, excision: Multiple (10) right pelvic lymph nodes are negative for tumor.

Lymph nodes, laparoscopic left pelvic, excision: Multiple (19) left pelvic lymph nodes are negative for tumor.

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s).

Dual/Synchronous Tumor Noted		/

Source: NCI Genomic Data Commons file 801662f4-ed15-4f28-b115-53bb936ae5f5 (TCGA-D1-A16I.3D30B053-444A-4F4D-B451-EB8746A157A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).